Gene-level copy-number profile of tumor specimen TCGA-43-6647-01A from TCGA case TCGA-43-6647, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.5 years (25,378 days).
Specimen TCGA-43-6647-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f2db409d-8122-41d0-b37e-181d9acc60ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-6647-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07b0f21f-2cfe-4454-9f88-3db69bb04712

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 13,464; copy number 2: 40,236; copy number 3: 4,103; copy number 4: 871; copy number 5: 737; copy number 6: 104; copy number 7: 24; copy number 8: 61; copy number 9: 46; copy number 10: 52; copy number 13: 17; copy number 17: 13; copy number 28: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-6647-01A-11D-1816-01): tumor purity 0.25, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,135,598–23,438,700, 56 genes (within-gene range 0–2): AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:27,829,276–31,166,980, 23 genes: AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,064 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:59,014,354–61,860,298, 56 genes, copy number 9–13: AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2.
- chr2:61,868,432–61,886,082, 1 gene, copy number 9 (within-gene range 2–9): AC107081.1.
- chr4:52,252,820–56,328,625, 79 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr4:134,932,889–144,343,750, 128 genes, copy number 6–7 (broad region; genes not listed).
- chr4:175,286,605–176,002,664, 8 genes, copy number 5–9 (within-gene range 1–9): AC095050.2, AC095050.1, AC131094.1, TSEN2P1, ADAM20P2, GPM6A, AC097537.1, AC110794.1.
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr8:36,378,069–38,468,834, 59 genes, copy number 8 (within-gene range 1–8): AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22.
- chr18:25,818,234–26,657,401, 18 genes, copy number 17–28: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P.
- chr18:26,685,954–26,832,432, 5 genes, copy number 28: AC012588.1, PCAT18, U3, AC018371.1, AC018371.2.

Autosomal genes at a single copy (total copy number 1): 13,464. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
